Somatic mutation profile of tumor specimen C3L-04976-54 (aliquot CPT0340440002) from CPTAC case C3L-04976, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.1 years (25,251 days).
Specimen C3L-04976-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b546639a-ce47-465e-835a-615113e0689e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04976-50 (Buccal Cell Normal), aliquot CPT0340410004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c1788bb-a4f5-4c72-a85a-685c269a6932

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insCACG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- MTBP | c.242T>A p.F81Y | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PKDREJ | c.5572T>A p.Y1858N | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RREB1 | c.3782T>A p.L1261Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- PREX2 | c.3735T>C p.C1245= | Silent (SNP) | VAF 50/136 reads (37%) | called by muse, varscan2
